Somatic mutation profile of tumor specimen TCGA-CZ-5986-01A (aliquot TCGA-CZ-5986-01A-11D-1669-08) from TCGA case TCGA-CZ-5986, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 61.5 years (22,456 days).
Specimen TCGA-CZ-5986-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5b3b010-5d0c-4c38-9c10-56c2e40aab8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5986-11A (Solid Tissue Normal), aliquot TCGA-CZ-5986-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3babf24-af30-407a-bba6-c37699ec744f

The open-access MAF lists 61 somatic variants for this specimen: 47 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 34, Silent 14, Frame Shift Del 5, In Frame Del 4, Splice Site 2, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+1_463+26del p.X155_splice | Splice Site (DEL) | VAF 41/122 reads (34%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- AC098582.1 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs759601114, COSV52024623; called by muse, mutect2, varscan2
- ANKRD52 | c.977T>A p.I326N | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57287480; called by muse, mutect2, varscan2
- ANKRD7 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV54554779, COSV54556519; called by muse, mutect2, varscan2
- AUNIP | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 92/289 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs778926533, COSV65353386; called by muse, mutect2, varscan2
- BBS4 | c.1395T>G p.N465K | Missense Mutation (SNP) | VAF 90/306 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.068); catalogued as rs759827273, COSV51440440; called by muse, mutect2, varscan2
- BTBD11 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV55027336, COSV55037424; called by muse, mutect2, varscan2
- CTR9 | c.911T>A p.M304K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV63729649; called by muse, mutect2, varscan2
- DNMT1 | c.4520A>G p.H1507R | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61583807; called by muse, mutect2
- FAM169A | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV65847275; called by muse, mutect2, varscan2
- FAM169A | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV65847285; called by muse, mutect2, varscan2
- GGT7 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV60542723; called by muse, mutect2, varscan2
- GOLGA3 | c.4055A>T p.K1352I | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52643198; called by muse, mutect2, varscan2
- GSTM2 | c.662A>C p.*221Sext*72 | Nonstop Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV99859964; called by muse, mutect2
- MED16 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54131610; called by muse, mutect2, varscan2
- NCAPD3 | c.694T>A p.L232M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.872); catalogued as COSV73258758; called by muse, mutect2, varscan2
- NECAB1 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs767867163, COSV70244247; called by mutect2, varscan2
- NFASC | c.3139A>T p.N1047Y | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV58379980; called by muse, mutect2, varscan2
- NSD2 | c.3932C>T p.T1311I | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as COSV56396452; called by muse, mutect2, varscan2
- OR10G4 | c.582C>A p.N194K | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.44); catalogued as COSV57977349; called by muse, mutect2, varscan2
- OR6C6 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as COSV64456269; called by muse, mutect2, varscan2
- PADI3 | c.1814C>G p.P605R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV64935402; called by muse, mutect2, varscan2
- PDLIM4 | c.412G>C p.G138R | Missense Mutation (SNP) | VAF 68/296 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.383); catalogued as COSV53805391; called by muse, mutect2, varscan2
- PHLPP2 | c.2881T>G p.W961G | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.998); catalogued as COSV62427209; called by muse, mutect2, varscan2
- PKD2L1 | c.235+1G>A p.X79_splice | Splice Site (SNP) | VAF 33/102 reads (32%) | catalogued as rs779833821, COSV58398846; called by muse, mutect2, varscan2
- PRDM11 | c.1030G>A p.E344K (on ENST00000530656 / NM_001359633.1; = p.E310K on NM_001256695.1) | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55443702; called by muse, mutect2, varscan2
- RERG | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 140/500 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57005235; called by muse, varscan2
- RSPRY1 | c.1055G>C p.C352S | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); catalogued as COSV68028680; called by muse, mutect2
- RSPRY1 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 70/198 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV68028685; called by muse, mutect2
- SLC10A7 | c.149T>C p.I50T | Missense Mutation (SNP) | VAF 115/450 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53890571; called by muse, mutect2, varscan2
- SLC22A13 | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as COSV61292154, COSV61292403; called by muse, mutect2, varscan2
- SOX5 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 88/236 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557463084, COSV58646879, COSV58648253; called by muse, mutect2, varscan2
- TLN1 | c.1900C>A p.R634S | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV59211777; called by muse, mutect2
- TTLL4 | c.1738T>A p.F580I | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51439445; called by muse, mutect2, varscan2
- VPS13D | c.9175G>A p.E3059K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as COSV50653537, COSV50683542; called by muse, mutect2, varscan2
- WDR91 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV60371873; called by muse, mutect2, varscan2
- YIPF4 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1350432104, COSV53215023; called by muse, mutect2, varscan2
- AJUBA | c.1293_1298del p.C432_N433del | In Frame Del (DEL) | VAF 25/102 reads (25%) | called by mutect2, pindel, varscan2
- ATM | c.2247del p.K750Sfs*3 | Frame Shift Del (DEL) | VAF 31/117 reads (26%) | called by mutect2, pindel, varscan2
- GOLGA2 | c.2935del p.A979Lfs*7 | Frame Shift Del (DEL) | VAF 30/171 reads (18%) | called by mutect2, pindel, varscan2
- HMCN1 | c.7095_7106del p.V2366_A2369del | In Frame Del (DEL) | VAF 41/181 reads (23%) | called by mutect2, pindel, varscan2
- IQGAP1 | c.4504del p.E1502Nfs*2 | Frame Shift Del (DEL) | VAF 24/95 reads (25%) | called by mutect2, pindel, varscan2
- KMT2C | c.14344_14346delinsT p.G4782Sfs*10 | Frame Shift Del (DEL) | VAF 48/184 reads (26%) | called by pindel, varscan2*
- PBRM1 | c.624del p.Q209Rfs*15 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- SLF1 | c.2950dup p.T984Nfs*5 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | called by pindel, varscan2
- SYCP2 | c.4274_4285del p.F1425_D1428del | In Frame Del (DEL) | VAF 16/77 reads (21%) | called by mutect2, pindel, varscan2
- TRIM6 | c.404_406del p.E135del | In Frame Del (DEL) | VAF 12/59 reads (20%) | called by pindel, varscan2
- ADCK2 | c.522G>A p.V174= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV50783530; called by muse, mutect2, varscan2
- ATP11A | c.2118G>A p.R706= | Silent (SNP) | VAF 31/81 reads (38%) | catalogued as COSV52124363; called by muse, mutect2, varscan2
- CAT | c.972T>C p.N324= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV53813365; called by muse, mutect2, varscan2
- CEACAM5 | c.177C>A p.P59= | Silent (SNP) | VAF 52/164 reads (32%) | catalogued as COSV55755147; called by muse, mutect2, varscan2
- CORIN | c.909T>C p.H303= | Silent (SNP) | VAF 12/165 reads (7%) | catalogued as COSV56699307; called by muse, mutect2
- CSMD2 | c.3222C>T p.T1074= | Silent (SNP) | VAF 105/285 reads (37%) | catalogued as rs760608600, COSV53880145, COSV99593430; called by muse, mutect2, varscan2
- GPR4 | c.180C>T p.S60= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV59918278; called by muse, mutect2, varscan2
- IL27RA | c.849C>G p.T283= | Silent (SNP) | VAF 89/314 reads (28%) | catalogued as COSV54603141; called by muse, mutect2, varscan2
- IQCN | c.1341G>A p.G447= | Silent (SNP) | VAF 45/137 reads (33%) | catalogued as COSV66577758; called by muse, mutect2, varscan2
- MUC20 | c.1587C>A p.P529= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV57854774; called by muse, mutect2, varscan2
- NLRP4 | c.159A>G p.E53= | Silent (SNP) | VAF 41/118 reads (35%) | catalogued as rs775600171, COSV56723199; called by muse, mutect2, varscan2
- OR4S2 | c.594A>T p.T198= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as COSV56748385; called by muse, mutect2
- PCDHGA1 | c.2097G>A p.A699= | Silent (SNP) | VAF 46/206 reads (22%) | catalogued as COSV65295607, COSV65299536; called by muse, mutect2, varscan2
- PRDM11 | c.1029G>A p.L343= (on ENST00000530656 / NM_001359633.1; = p.L309= on NM_001256695.1) | Silent (SNP) | VAF 88/261 reads (34%) | catalogued as rs768274470, COSV55443682; called by muse, mutect2, varscan2
